Somatic mutation profile of tumor specimen ASCProject_0202_T1_WES (aliquot ASCProject_0202_T1_WES_1) from CMI case ASCProject_0202, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: female; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 51.9 years (18,947 days).
Specimen ASCProject_0202_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0d200bb-c0b3-430c-bdcb-62f56753a11e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0202_SALIVA (Saliva), aliquot ASCProject_0202_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b505f6a-a9c4-4766-9be9-083a1586e829

The open-access MAF lists 80 somatic variants for this specimen: 52 protein-altering or splice-affecting, 21 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 21, Nonsense Mutation 4, Intron 4, 3'UTR 2, Frame Shift Del 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 25/161 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs104894228, CM060018, COSV54236651, COSV54236730, COSV54241641; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM29 | c.778G>T p.D260Y | Missense Mutation (SNP) | VAF 13/160 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1274314778; called by muse, mutect2
- AFAP1L1 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1164873346; called by muse, mutect2, varscan2
- AGO4 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1557558957, COSV64616683; called by muse, mutect2
- AGRN | c.5483A>G p.N1828S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs753473191; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP11A | c.2392C>T p.R798C | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756233070; called by muse, mutect2, varscan2
- CARD6 | c.620T>C p.L207S | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs954216773; called by muse, mutect2, varscan2
- DGKI | c.2038G>A p.D680N | Missense Mutation (SNP) | VAF 60/314 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55952663; called by muse, mutect2, varscan2
- DPYS | c.1330G>A p.G444S | Missense Mutation (SNP) | VAF 79/401 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757526378; called by muse, mutect2, varscan2
- FCRL4 | c.188G>A p.W63* | Nonsense Mutation (SNP) | VAF 131/396 reads (33%) | catalogued as COSV54859462; called by muse, mutect2, varscan2
- GTF3C1 | c.2492C>T p.T831M | Missense Mutation (SNP) | VAF 40/480 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs531481141; called by muse, mutect2
- IL2RG | c.341G>T p.G114V | Missense Mutation (SNP) | VAF 41/249 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD982710, CM930432; called by muse, mutect2, varscan2
- KCNH5 | c.1996C>T p.L666F | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1363233289; called by muse, mutect2
- MICU2 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.989); catalogued as rs760237154; called by muse, mutect2, varscan2
- MUC12 | c.3545C>T p.T1182I (on ENST00000379442; = p.T1039I on NM_001164462.1) | Missense Mutation (SNP) | VAF 36/850 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.517); catalogued as rs768921497; called by muse, mutect2
- MVP | c.1739G>A p.R580Q | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1444675404; called by muse, mutect2, varscan2
- NAA11 | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.755); catalogued as rs1261869628, COSV54515250; called by muse, mutect2
- NSD1 | c.5649G>T p.Q1883H | Missense Mutation (SNP) | VAF 54/426 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as COSV61785120; called by muse, mutect2, varscan2
- OR5D14 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as rs750038669; called by muse, mutect2, varscan2
- PHF3 | c.4336G>A p.V1446M | Missense Mutation (SNP) | VAF 55/229 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100012809; called by muse, mutect2, varscan2
- PLAG1 | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 54/220 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs935625762; called by muse, mutect2, varscan2
- SCARB1 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 66/289 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV55551116; called by muse, mutect2, varscan2
- SLC16A12 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs758404955, COSV57947568; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TBX22 | c.1336G>A p.G446R | Missense Mutation (SNP) | VAF 105/509 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.578); catalogued as COSV64786174; called by muse, mutect2, varscan2
- TLR9 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.157); catalogued as rs199736549, COSV62346613; called by muse, mutect2, varscan2
- TMEM59 | c.33G>T p.R11S | Missense Mutation (SNP) | VAF 36/242 reads (15%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs774562604; called by muse, mutect2, varscan2
- TMEM59L | c.733G>A p.V245M | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.055); catalogued as rs1182701814; called by muse, mutect2, varscan2
- AC245033.1 | c.1432C>T p.H478Y | Missense Mutation (SNP) | VAF 162/876 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- ALLC | c.396G>A p.W132* | Nonsense Mutation (SNP) | VAF 47/268 reads (18%) | called by muse, mutect2, varscan2
- BMP7 | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 77/385 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- C2CD2 | c.990G>T p.Q330H | Missense Mutation (SNP) | VAF 73/420 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FAM83B | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 53/282 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GLP1R | c.99G>A p.W33* | Nonsense Mutation (SNP) | VAF 22/88 reads (25%) | called by muse, mutect2, varscan2
- GPR108 | c.1007_1007+13del p.X336_splice (on ENST00000264080 / NM_001080452.1; = p.X94_splice on NM_020171.2) | Splice Site (DEL) | VAF 38/205 reads (19%) | called by mutect2, pindel, varscan2
- GPR162 | c.499G>A p.G167S | Missense Mutation (SNP) | VAF 49/286 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- GPR19 | c.1103A>G p.K368R | Missense Mutation (SNP) | VAF 46/327 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- H2BC15 | c.41G>C p.G14A | Missense Mutation (SNP) | VAF 45/218 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.988); called by muse, mutect2
- KIAA1671 | c.3389T>A p.L1130* | Nonsense Mutation (SNP) | VAF 72/325 reads (22%) | called by muse, mutect2, varscan2
- LRCH2 | c.2044G>T p.A682S | Missense Mutation (SNP) | VAF 61/375 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRRC36 | c.2209A>G p.T737A | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- NAALADL1 | c.1804_1807del p.A602Pfs*20 | Frame Shift Del (DEL) | VAF 21/156 reads (13%) | called by pindel, varscan2
- NBPF15 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 70/882 reads (8%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- NMNAT3 | c.671T>A p.I224N (on ENST00000296202 / NM_001320512.1; = p.I187N on NM_178177.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- OXCT1 | c.1257G>A p.M419I | Missense Mutation (SNP) | VAF 57/508 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PTPRO | c.2388T>A p.F796L | Missense Mutation (SNP) | VAF 73/396 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- RASGRF2 | c.1811C>T p.S604F | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- SBNO1 | c.305C>A p.T102K (on ENST00000420886; = p.T101K on NM_018183.5) | Missense Mutation (SNP) | VAF 39/225 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- SCARF1 | c.1042G>A p.G348R | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC16A9 | c.1468A>G p.N490D | Missense Mutation (SNP) | VAF 46/275 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TCOF1 | c.1129C>T p.P377S (on ENST00000377797 / NM_001135243.1; = p.P300S on NM_000356.4) | Missense Mutation (SNP) | VAF 72/354 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TESC | c.544A>T p.I182F | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZNF181 | c.95T>G p.V32G | Missense Mutation (SNP) | VAF 42/241 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CEP290 | c.4365C>T p.I1455= | Silent (SNP) | VAF 55/353 reads (16%) | catalogued as rs552731286; called by muse, mutect2, varscan2
- DCHS1 | c.567G>A p.E189= | Silent (SNP) | VAF 29/131 reads (22%) | called by muse, mutect2, varscan2
- DNAH17 | c.1272C>T p.I424= | Silent (SNP) | VAF 32/151 reads (21%) | called by muse, mutect2, varscan2
- DNAI1 | c.441C>T p.D147= | Silent (SNP) | VAF 78/391 reads (20%) | catalogued as rs374753293; called by muse, mutect2, varscan2
- DRGX | c.225C>T p.A75= | Silent (SNP) | VAF 49/199 reads (25%) | called by muse, mutect2, varscan2
- DUOX2 | c.2691G>A p.K897= | Silent (SNP) | VAF 78/321 reads (24%) | called by muse, mutect2, varscan2
- FBXO10 | c.840A>T p.S280= | Silent (SNP) | VAF 56/245 reads (23%) | called by muse, mutect2, varscan2
- GRM3 | c.969G>A p.L323= | Silent (SNP) | VAF 45/244 reads (18%) | catalogued as COSV100862730; called by muse, mutect2, varscan2
- LIME1 | c.810C>T p.C270= | Silent (SNP) | VAF 28/128 reads (22%) | catalogued as rs971859599; called by muse, mutect2, varscan2
- OR2T2 | c.306C>T p.I102= | Silent (SNP) | VAF 85/867 reads (10%) | catalogued as COSV61619311; called by muse, mutect2, varscan2
- P2RX1 | c.108C>T p.I36= | Silent (SNP) | VAF 43/222 reads (19%) | catalogued as rs372753831; called by muse, mutect2, varscan2
- PPP2R1B | c.1443A>G p.L481= | Silent (SNP) | VAF 54/265 reads (20%) | called by muse, mutect2, varscan2
- RASGRF2 | c.1812C>T p.S604= | Silent (SNP) | VAF 19/94 reads (20%) | called by muse, mutect2, varscan2
- RBM15 | c.276T>C p.G92= | Silent (SNP) | VAF 21/296 reads (7%) | catalogued as rs767492348; called by muse, mutect2
- RRN3 | c.1581C>A p.T527= | Silent (SNP) | VAF 26/149 reads (17%) | called by muse, mutect2, varscan2
- TCOF1 | c.1128C>T p.A376= (on ENST00000377797 / NM_001135243.1; = p.A299= on NM_000356.4) | Silent (SNP) | VAF 74/358 reads (21%) | called by muse, mutect2, varscan2
- TMEM59L | c.732G>A p.K244= | Silent (SNP) | VAF 35/207 reads (17%) | called by muse, mutect2, varscan2
- UBR5 | c.6237C>T p.A2079= | Silent (SNP) | VAF 66/395 reads (17%) | called by muse, mutect2, varscan2
- UNC5B | c.67C>T p.L23= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs1394341859; called by muse, mutect2
- UTRN | c.9312A>G p.A3104= | Silent (SNP) | VAF 66/374 reads (18%) | catalogued as rs764823354; called by muse, mutect2, varscan2
- ZNF234 | c.411A>C p.G137= | Silent (SNP) | VAF 24/113 reads (21%) | called by muse, mutect2, varscan2
- DST | c.4297-4775G>A | Intron (SNP) | VAF 32/141 reads (23%) | catalogued as COSV55014983; called by muse, mutect2, varscan2
- DYNC1I1 | c.365+5213A>C | Intron (SNP) | VAF 24/115 reads (21%) | catalogued as rs1380844926; called by muse, mutect2, varscan2
- ECSIT | c.796+9G>A | Intron (SNP) | VAF 46/279 reads (16%) | catalogued as rs368448235; called by muse, mutect2, varscan2
- ELK1 | c.*36_*38del | 3'UTR (DEL) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- HEPACAM2 | c.*67A>G | 3'UTR (SNP) | VAF 38/143 reads (27%) | catalogued as rs964428701, COSV100506317; called by muse, mutect2, varscan2
- HERC2P3 | n.897G>A | RNA (SNP) | VAF 45/503 reads (9%) | catalogued as rs779713761; called by muse, mutect2
- PSPH | c.141-26G>A | Intron (SNP) | VAF 49/233 reads (21%) | called by muse, mutect2, varscan2
